Gene-level copy-number profile of tumor specimen TARGET-40-0A4I48-01A from TARGET case TARGET-40-0A4I48, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.0 years (5,854 days).
Specimen TARGET-40-0A4I48-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.94df3caa-c583-5d0e-83d9-50b782c47e16.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I48-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 414 have no estimate.
https://portal.gdc.cancer.gov/files/302b030f-0f11-42a6-bef5-4060aee461e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 10,986; copy number 2: 28,054; copy number 3: 16,339; copy number 4: 2,476; copy number 5: 811; copy number 6: 572; copy number 7: 120; copy number 8: 14; copy number 10: 150; copy number 11: 32; copy number 22: 29; copy number 23: 7; copy number 24: 32; copy number 25: 13; copy number 28: 2; copy number 33: 36.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,782,805–166,029,311, 3 genes: AC008562.1, AC008489.1, RPL7P20.
- chr7:147,080,934–147,378,121, 4 genes: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr11:84,545,131–84,546,846, 1 gene: HNRNPA1P72.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,818 genes in 63 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,384,398–84,397,831, 258 genes, copy number 5 (broad region; genes not listed).
- chr2:88,857,161–89,969,335, 68 genes, copy number 10 (broad region; genes not listed).
- chr2:125,665,331–130,441,413, 118 genes, copy number 6 (broad region; genes not listed).
- chr2:133,596,091–135,531,218, 18 genes, copy number 5 (within-gene range 3–5): RN7SKP93, AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3.
- chr2:140,216,997–142,131,016, 11 genes, copy number 5–7 (within-gene range 3–7): MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:144,877,734–155,664,668, 117 genes, copy number 5–8 (broad region; genes not listed).
- chr2:157,526,767–168,247,595, 129 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:199,760,544–201,009,102, 32 genes, copy number 24 (within-gene range 4–24): FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1.
- chr3:99,500,347–100,401,089, 15 genes, copy number 6 (within-gene range 4–6): AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70.
- chr3:191,329,085–192,119,864, 8 genes, copy number 5 (within-gene range 2–5): CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222.
- chr4:11,368,827–11,823,906, 8 genes, copy number 5–6 (within-gene range 4–6): MIR572, RNPS1P1, HS3ST1, RNA5SP156, AC006230.1, AC025539.1, AC005699.1, LINC02360.
- chr4:25,622,777–26,490,484, 16 genes, copy number 6–7: AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR.
- chr4:28,435,449–29,963,758, 16 genes, copy number 5 (within-gene range 3–5): AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17.
- chr4:33,400,538–34,039,914, 6 genes, copy number 6: AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1.
- chr4:42,281,830–43,234,956, 10 genes, copy number 5 (within-gene range 1–5): AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1.
- chr6:1,601,654–2,750,922, 13 genes, copy number 25 (within-gene range 2–25): FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4.
- chr6:39,188,971–49,360,420, 226 genes, copy number 5–11 (broad region; genes not listed).
- chr6:49,823,712–50,181,007, 8 genes, copy number 6 (within-gene range 1–6): AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr6:151,196,681–151,358,559, 7 genes, copy number 5 (within-gene range 3–5): AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268.
- chr8:110,105,076–120,056,201, 79 genes, copy number 5–6 (broad region; genes not listed).
- chr8:126,325,454–128,564,679, 36 genes, copy number 33: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:132,507,962–133,756,646, 25 genes, copy number 11: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49.
- chr12:389,273–2,697,950, 40 genes, copy number 5 (within-gene range 3–5): CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1.
- chr12:7,108,052–8,949,761, 99 genes, copy number 5 (broad region; genes not listed).
- chr12:25,779,287–26,833,194, 22 genes, copy number 5 (within-gene range 2–5): RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1.
- chr14:24,505,353–24,657,774, 5 genes, copy number 5 (within-gene range 4–5): CMA1, CTSG, AL136018.1, GZMH, GZMB.
- chr14:25,267,064–30,191,898, 45 genes, copy number 6–8 (within-gene range 3–8): HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P.
- chr14:31,291,788–34,659,878, 45 genes, copy number 5–7 (within-gene range 3–7): HEATR5A, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1, NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP.
- chr14:44,392,531–45,715,952, 28 genes, copy number 6: AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303.
- chr14:46,839,629–47,675,605, 5 genes, copy number 6 (within-gene range 3–6): MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3.
- chr14:88,180,103–89,111,223, 15 genes, copy number 5 (within-gene range 3–5): KCNK10, SPATA7, PTPN21, AL162171.2, RNU4-22P, AL162171.1, ZC3H14, AL162171.3, EML5, AL121768.1, RNU4-92P, TTC8, Y_RNA, AL137785.1, MPPE1P1.
- chr14:105,881,034–106,344,833, 80 genes, copy number 10 (broad region; genes not listed).
- chr15:89,201,091–90,138,016, 44 genes, copy number 5: AC124068.1, RLBP1, FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT.
- chr15:96,756,987–97,432,094, 6 genes, copy number 23 (within-gene range 3–23): FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1.
- chr15:98,282,075–99,498,375, 29 genes, copy number 22: AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4.
- chr16:69,762,328–71,230,722, 44 genes, copy number 5 (within-gene range 3–5): WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1, HYDIN, RNU6ATAC25P.
- chr16:74,282,415–74,666,877, 18 genes, copy number 5 (within-gene range 3–5): AC009120.4, AC009120.5, PSMD7, AC009120.2, AC009120.1, AC009120.3, AC009053.1, AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3, GLG1, RNU6-237P, Y_RNA, AC009153.1, HSPE1P7, RFWD3.
- chr16:79,676,048–80,563,354, 7 genes, copy number 5 (within-gene range 3–5): LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1, AC105411.1, AC022166.2.
- chr19:29,233,090–29,617,237, 8 genes, copy number 5: RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4.
- chr21:22,882,582–23,490,724, 12 genes, copy number 5: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.

Autosomal genes at a single copy (total copy number 1): 9,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
